Somatic mutation profile of tumor specimen TARGET-20-PARCVS-03A (aliquot TARGET-20-PARCVS-03A-02D) from TARGET case TARGET-20-PARCVS, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.3 years (5,600 days).
Specimen TARGET-20-PARCVS-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2271e7d6-5004-4391-b001-256e9b8c9aca.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARCVS-14A (Bone Marrow Normal), aliquot TARGET-20-PARCVS-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c2abace-0eaa-4ffe-a4ab-f71b26cc196d

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Silent 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2446G>C p.D816H | Missense Mutation (SNP) | VAF 73/251 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as rs121913506, COSV55386862, COSV55387240, COSV55408330; ClinVar: likely pathogenic / other / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 23/187 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- GAREM1 | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 116/296 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52509279; called by muse, mutect2, varscan2
- PRKDC | c.12269G>A p.R4090H | Missense Mutation (SNP) | VAF 81/178 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs769900148, COSV58051561; called by muse, mutect2, varscan2
- SUPT5H | c.3242T>A p.L1081Q | Missense Mutation (SNP) | VAF 69/146 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58679447; called by muse, mutect2, varscan2
- CREBBP | c.1760dup p.V588Cfs*20 | Frame Shift Ins (INS) | VAF 70/185 reads (38%) | called by mutect2, pindel, varscan2
- TET2 | c.3478A>T p.I1160F | Missense Mutation (SNP) | VAF 20/259 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- TET2 | c.4361_4377del p.V1454Afs*18 | Frame Shift Del (DEL) | VAF 22/242 reads (9%) | called by mutect2, pindel
- TET2 | c.3477T>G p.A1159= | Silent (SNP) | VAF 20/256 reads (8%) | called by muse, mutect2
